Somatic mutation profile of tumor specimen TCGA-DD-AAW1-01A (aliquot TCGA-DD-AAW1-01A-11D-A40P-10) from TCGA case TCGA-DD-AAW1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 55.5 years (20,288 days).
Specimen TCGA-DD-AAW1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d676963d-8c4d-461b-b8fe-d6f418947fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAW1-10A (Blood Derived Normal), aliquot TCGA-DD-AAW1-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc73e25d-8543-458e-a7d0-0708d1dcd042

The open-access MAF lists 127 somatic variants for this specimen: 97 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 26, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 3, Intron 3, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 90/182 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1827A>T p.K609N | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99713958; called by muse, mutect2, varscan2
- ADGRB2 | c.2147T>A p.L716Q | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99926743; called by muse, mutect2, varscan2
- ADIPOQ | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57859869; called by muse, mutect2, varscan2
- AKAP13 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100774323; called by muse, mutect2, varscan2
- ALK | c.2200T>A p.Y734N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101202517; called by muse, mutect2
- ANO5 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs781734224, COSV100202056, COSV61089564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCLAF1 | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773332392, COSV99219770; called by muse, mutect2, varscan2
- CCDC105 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748997369, COSV99480057; called by muse, mutect2, varscan2
- CCDC180 | c.1075A>T p.I359F | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs919077615, COSV100827223; called by muse, mutect2, varscan2
- CCDC39 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99870246; called by muse, mutect2, varscan2
- CCHCR1 | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV99456251; called by muse, mutect2, varscan2
- CEACAM5 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.784); catalogued as COSV55750352; called by muse, mutect2, varscan2
- CFAP44 | c.1289A>T p.K430I | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99870211; called by muse, mutect2, varscan2
- CHCHD2 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV101271056; called by muse, mutect2, varscan2
- CLIP2 | c.1696A>T p.K566* | Nonsense Mutation (SNP) | VAF 67/173 reads (39%) | catalogued as COSV99792085; called by muse, mutect2, varscan2
- CLK2 | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100751910; called by muse, mutect2, varscan2
- CLNK | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99905640; called by muse, mutect2, varscan2
- COL19A1 | c.2752C>G p.P918A | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs369271643, COSV59590102; called by muse, mutect2, varscan2
- CYP4B1 | c.457T>A p.Y153N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99597375; called by muse, mutect2, varscan2
- DDX18 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 190/502 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99604710; called by muse, mutect2, varscan2
- DENND2A | c.2614A>T p.R872W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99326726; called by muse, mutect2, varscan2
- DIPK2A | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.763); catalogued as COSV100237406; called by muse, mutect2, varscan2
- DIPK2A | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV100237408; called by muse, mutect2, varscan2
- DISP3 | c.3170A>T p.K1057M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99609682; called by muse, mutect2, varscan2
- DLGAP3 | c.2000+2T>A p.X667_splice | Splice Site (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99333065; called by muse, mutect2, varscan2
- DLGAP5 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55963170, COSV99904085; called by muse, mutect2, varscan2
- DNAAF4 | c.619A>T p.R207* | Nonsense Mutation (SNP) | VAF 84/226 reads (37%) | catalogued as COSV100336881; called by muse, mutect2, varscan2
- DNAJC27 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV99266721; called by muse, mutect2, varscan2
- DOT1L | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs1329819181, COSV67109804; called by muse, mutect2, varscan2
- ENTHD1 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | catalogued as COSV100289022; called by muse, mutect2, varscan2
- EXD2 | c.1006A>T p.R336* (on ENST00000312994 / NM_001193362.1; = p.R211* on NM_018199.3) | Nonsense Mutation (SNP) | VAF 77/171 reads (45%) | catalogued as COSV100474368; called by muse, mutect2, varscan2
- FAS | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100570870; called by muse, mutect2, varscan2
- GIGYF2 | c.3101del p.H1034Lfs*16 | Frame Shift Del (DEL) | VAF 45/115 reads (39%) | catalogued as CM096344; called by mutect2, pindel, varscan2
- GRIK1 | c.2552T>A p.F851Y | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100517598; called by muse, mutect2, varscan2
- HELQ | c.1733A>T p.Y578F | Missense Mutation (SNP) | VAF 274/680 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99788034; called by muse, mutect2, varscan2
- IKZF1 | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100498649; called by muse, mutect2, varscan2
- ISCU | c.358A>T p.I120F (on ENST00000311893 / NM_213595.4; = p.I95F on NM_014301.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100318470; called by muse, mutect2, varscan2
- ITGA2 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.913); catalogued as COSV99671384; called by muse, mutect2, varscan2
- KCNH7 | c.1630T>A p.Y544N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100037295; called by muse, mutect2, varscan2
- KIF14 | c.3066A>G p.I1022M | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV100951009; called by muse, mutect2, varscan2
- KIRREL3 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV101292436; called by muse, mutect2, varscan2
- KRTAP10-7 | c.974T>A p.V325D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100170280; called by muse, mutect2, varscan2
- MMADHC | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100307295; called by muse, mutect2
- MMP10 | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV99666723; called by muse, mutect2, varscan2
- MMP28 | c.1180T>A p.W394R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539276001; called by muse, mutect2, varscan2
- MPP1 | c.103-1G>A p.X35_splice | Splice Site (SNP) | VAF 71/83 reads (86%) | catalogued as COSV101053733; called by muse, mutect2, varscan2
- MROH9 | c.1658C>A p.S553* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV63012188; called by muse, mutect2, varscan2
- MST1 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99611003; called by muse, mutect2, varscan2
- MTUS2 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV101462333, COSV70916454; called by muse, mutect2
- NAA16 | c.1976A>T p.K659M | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101050136; called by muse, mutect2, varscan2
- NLRP12 | c.2116G>C p.A706P | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.864); catalogued as COSV100145661; called by muse, mutect2, varscan2
- NOL4L | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs369527139; called by muse, mutect2, varscan2
- NOP2 | c.2237A>G p.H746R (on ENST00000322166 / NM_001258308.2; = p.H742R on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as COSV100351326; called by muse, mutect2, varscan2
- NR2C2 | c.1676A>G p.E559G (on ENST00000393102; = p.E578G on NM_003298.5) | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038776; called by muse, mutect2, varscan2
- OR1L3 | c.29_30del p.S10* | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs1564232922; called by pindel, varscan2
- OR7G3 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100555731, COSV59641201; called by muse, mutect2, varscan2
- PADI4 | c.1966T>A p.F656I | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100966901; called by muse, mutect2, varscan2
- PAX7 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1372477155, COSV100946939; called by muse, mutect2, varscan2
- PCLO | c.14869A>G p.S4957G | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV100436280, COSV61641398; called by muse, mutect2
- PLCL1 | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70883989; called by muse, mutect2, varscan2
- PPP1R12A | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.889); catalogued as COSV99700693; called by muse, mutect2, varscan2
- PRAMEF17 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 141/232 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV101068783; called by muse, mutect2, varscan2
- PTPRT | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100629583; called by muse, mutect2, varscan2
- PYGO2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 111/195 reads (57%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.829); catalogued as COSV100868977; called by muse, mutect2, varscan2
- RYR1 | c.13304A>G p.D4435G | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100616640; called by muse, mutect2
- SLC25A6 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101195488; called by muse, mutect2, varscan2
- SLC7A3 | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 360/390 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99979757; called by muse, varscan2
- SMYD2 | c.888A>T p.R296S | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100873288; called by muse, mutect2, varscan2
- SPA17 | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 39/137 reads (28%) | catalogued as COSV99907228; called by muse, mutect2, varscan2
- SRC | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV100658180; called by muse, mutect2, varscan2
- STAB2 | c.6867C>G p.C2289W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101186222; called by muse, mutect2, varscan2
- STAP2 | c.856A>T p.K286* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99696971; called by muse, mutect2, varscan2
- SV2B | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100370869; called by muse, mutect2, varscan2
- TAS2R31 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV101115357; called by muse, varscan2
- TAS2R38 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV101516506; called by muse, mutect2, varscan2
- TAT | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100587711; called by muse, mutect2, varscan2
- TMEM131 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 334/816 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99489147; called by muse, mutect2, varscan2
- TMEM44 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99861951; called by muse, mutect2, varscan2
- TOP3B | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100592706; called by muse, mutect2, varscan2
- TRPM5 | c.1520T>A p.L507Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); catalogued as COSV99330422; called by muse, mutect2, varscan2
- WASL | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV56135952; called by muse, mutect2, varscan2
- ZBTB17 | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100999056; called by muse, mutect2, varscan2
- ZC3H12C | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99585245; called by muse, mutect2, varscan2
- ZFP1 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV100182143; called by muse, mutect2, varscan2
- ZNF17 | c.141A>G p.V47= | Splice Region (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100300147; called by muse, mutect2, varscan2
- ZNF264 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99567395; called by muse, mutect2, varscan2
- ZNF578 | c.787A>T p.I263L | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs199506035; called by muse, mutect2, varscan2
- DYNC1I2 | c.253_255dup p.P85dup | In Frame Ins (INS) | VAF 77/221 reads (35%) | called by mutect2, varscan2
- FAM166C | c.236del p.N79Tfs*4 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | called by mutect2, pindel, varscan2
- KMT2A | c.1142dup p.A383Gfs*6 | Frame Shift Ins (INS) | VAF 94/254 reads (37%) | called by mutect2, pindel, varscan2
- LONP2 | c.226del p.L76Cfs*26 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TPTE | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TPTE | c.1179T>A p.Y393* (on ENST00000618007 / NM_199261.4; = p.Y375* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 44/500 reads (9%) | called by muse, mutect2
- UNC13C | c.1625dup p.T543Hfs*3 | Frame Shift Ins (INS) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- USP54 | c.2255_2273del p.A752Efs*8 | Frame Shift Del (DEL) | VAF 35/96 reads (36%) | called by mutect2, pindel, varscan2
- ZNF800 | c.43_45del p.H15del | In Frame Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- ABCA8 | c.4524G>A p.L1508= | Silent (SNP) | VAF 100/372 reads (27%) | catalogued as COSV99286594; called by muse, mutect2, varscan2
- ARHGAP30 | c.1392T>A p.P464= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100920452; called by muse, mutect2, varscan2
- C15orf39 | c.2712G>A p.Q904= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs761991024, COSV100641437; called by muse, mutect2, varscan2
- CA10 | c.354T>A p.S118= | Silent (SNP) | VAF 87/281 reads (31%) | catalogued as COSV99564439; called by muse, mutect2, varscan2
- CDS1 | c.1149C>A p.I383= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99880999; called by muse, mutect2, varscan2
- CSMD2 | c.10386C>T p.Y3462= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as rs747855239, COSV53899871; called by muse, mutect2, varscan2
- DENND2A | c.1413A>T p.P471= | Silent (SNP) | VAF 77/157 reads (49%) | catalogued as COSV99326729; called by muse, mutect2, varscan2
- DMXL2 | c.264A>T p.I88= | Silent (SNP) | VAF 200/455 reads (44%) | catalogued as COSV99198071; called by muse, mutect2, varscan2
- FPR1 | c.378C>T p.C126= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs776424230, CM995226, COSV59053255; called by muse, varscan2
- LATS2 | c.1518C>T p.Y506= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs751957428, COSV66876633; called by muse, mutect2, varscan2
- MUC16 | c.11721G>A p.L3907= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as COSV101200858; called by muse, mutect2, varscan2
- MYLIP | c.561A>T p.I187= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as COSV100786009; called by muse, mutect2, varscan2
- OR5B21 | c.654A>T p.I218= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV100835171; called by muse, mutect2, varscan2
- OR8U1 | c.192C>T p.S64= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100164070; called by muse, mutect2, varscan2
- PAM | c.2592G>T p.V864= | Silent (SNP) | VAF 83/186 reads (45%) | catalogued as COSV99173724; called by muse, mutect2, varscan2
- PCDHGB7 | c.1758C>T p.Y586= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs780077182, COSV99544225; called by muse, mutect2, varscan2
- PKHD1L1 | c.102A>T p.T34= | Silent (SNP) | VAF 92/133 reads (69%) | catalogued as COSV101006667; called by muse, mutect2, varscan2
- PRAMEF20 | c.225A>T p.P75= | Silent (SNP) | VAF 198/492 reads (40%) | catalogued as COSV100326356; called by muse, mutect2, varscan2
- PXDN | c.3252G>A p.L1084= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99414552; called by muse, mutect2, varscan2
- SH3RF3 | c.1620A>T p.G540= | Silent (SNP) | VAF 77/164 reads (47%) | catalogued as COSV100513549; called by muse, mutect2, varscan2
- SLC2A1 | c.1215C>T p.A405= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs769506294, COSV65288102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA32 | c.687C>T p.S229= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as rs373812499, COSV100077560; called by muse, mutect2, varscan2
- TNN | c.1191T>A p.T397= | Silent (SNP) | VAF 81/133 reads (61%) | catalogued as COSV99512711; called by muse, mutect2, varscan2
- USP22 | c.1362G>A p.T454= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs1288810684, COSV99820437; called by muse, mutect2, varscan2
- ZBTB38 | c.1938T>C p.N646= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs758578318, COSV100375925; called by muse, mutect2, varscan2
- ZNF142 | c.1695C>A p.G565= (on ENST00000411696 / NM_001379660.1; = p.G365= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV101376983; called by muse, mutect2, varscan2
- CHCHD2P9 | n.306T>A | RNA (SNP) | VAF 42/105 reads (40%) | catalogued as rs886527247; called by muse, mutect2, varscan2
- EPHA6 | c.2784+10234T>A | Intron (SNP) | VAF 40/80 reads (50%) | catalogued as COSV101065031, COSV67575459; called by muse, mutect2, varscan2
- MEF2C | c.402+153dup | Intron (INS) | VAF 49/152 reads (32%) | catalogued as rs796052736; ClinVar: uncertain significance; called by mutect2, varscan2
- PGF | c.638+116G>A | Intron (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99462677; called by muse, mutect2, varscan2
